Gene-level copy-number profile of tumor specimen ALCH-B1YF-TTP1-A from ALCHEMIST case ALCH-B1YF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.1 years (23,786 days).
Specimen ALCH-B1YF-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file eb0b1443-8c35-4606-a2b2-332f623a0188.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1YF-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/1b1854d2-2197-40e9-bd67-76d0be1c8770

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 535; copy number 2: 56,624; copy number 3: 628; copy number 4: 453; copy number 5: 111; copy number 6: 1; copy number 7: 40; copy number 8: 2; copy number 13: 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:31,465,543–31,465,832, 1 gene (within-gene range 0–1): RN7SL79P.
- chr17:31,560,132–31,575,659, 5 genes: AC003101.2, RNU6ATAC7P, AC003101.1, MIR4725, MIR365B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 155 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:1,113,639–1,153,726, 3 genes, copy number 5 (within-gene range 4–5): AC092535.4, TMED11P, AC092535.1.
- chr8:79,259,402–80,539,135, 27 genes, copy number 5–7: AC138646.1, AC100870.1, RPL3P9, STMN2, HEY1, LINC01607, AC036214.1, RNU7-85P, AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2, TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3.
- chr8:83,293,925–83,294,271, 1 gene, copy number 6: AC090132.2.
- chr8:85,833,377–86,321,146, 9 genes, copy number 5: AC100801.1, LINC02849, ATP6V0D2, AC023194.1, AC023194.2, PSKH2, AC023194.3, AC084128.1, SLC7A13.
- chr8:97,624,203–98,294,393, 18 genes, copy number 7: AP002982.1, MTDH, Y_RNA, LAPTM4B, AP003357.1, AP002906.1, SUMO2P18, RPS23P1, MATN2, RPL30, AP003352.1, SNORA72, RNU6-703P, ERICH5, RIDA, POP1, NIPAL2, RNU6-914P.
- chr8:123,851,987–128,564,679, 79 genes, copy number 5–7 (broad region; genes not listed).
- chr8:129,832,301–130,443,674, 15 genes, copy number 7: AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1.
- chr21:43,414,483–43,427,131, 1 gene, copy number 13: SIK1.
- chr21:43,461,960–43,479,534, 2 genes, copy number 8: LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 535. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
